Gene-level copy-number profile of tumor specimen TCGA-DX-A48K-01A from TCGA case TCGA-DX-A48K, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 65.0 years (23,756 days).
Specimen TCGA-DX-A48K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.aedc5a57-02d2-4d9b-a984-48bb962c2a3a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A48K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bf9252ec-f4ee-427f-b1f1-986b305b4455

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 791; copy number 2: 8,739; copy number 3: 3,216; copy number 4: 38,695; copy number 5: 4,466; copy number 6: 3,172; copy number 7: 2; copy number 8: 107; copy number 9: 31; copy number 10: 22; copy number 12: 125; copy number 13: 108; copy number 18: 245; copy number 20: 65; copy number 30: 9; copy number 34: 5; copy number 45: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A48K-01A-11D-A306-01): tumor purity 0.64, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 630 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:21,483,834–27,171,811, 115 genes, copy number 13–20 (within-gene range 2–20) (broad region; genes not listed).
- chr15:85,380,571–85,749,358, 1 gene, copy number 9 (within-gene range 4–9): AKAP13.
- chr15:85,579,046–85,825,730, 14 genes, copy number 9: AC087286.3, AC087286.2, AC087286.1, RNU6-1280P, AC087286.4, AC021739.3, AC021739.2, AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1, RNU6-231P, MIR548AP.
- chr17:10,258,762–22,299,893, 450 genes, copy number 10–20 (broad region; genes not listed).
- chr17:22,420,022–22,568,713, 16 genes, copy number 9: AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2.
- chr19:28,394,851–29,824,312, 34 genes, copy number 30–45: AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1.

Autosomal genes at a single copy (total copy number 1): 783. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
